Surgical pathology report (de-identified scan), TCGA case TCGA-36-1576, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-1576-01A (Primary Tumor).

[page 1 of 2]
TCGA-36-1576

Surgical Pathology Consultation Report

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering Physician:

Final Diagnosis:

1. Specimen submitted labelled "left ovary and tube":

A. High-grade papillary serous adenocarcinoma of ovary.

B. Focal area of high-grade carcinoma in vascular stroma of fallopian tube (see Comment).

2. Specimen submitted labelled "right ovary and fallopian tube" with:

A. Multiple small foci of high-grade carcinoma involving ovary -

Consistent with high-grade papillary serous adenocarcinoma.

B. Multiple small foci of high-grade carcinoma on external surface of fallopian tube. See Comment.

Final Diagnosis Comment:

The carcinoma is similar in both ovaries and on the surface of both fallopian tubes. The appearance is consistent with high-grade papillary serous adenocarcinoma of ovarian origin. There is extensive necrosis in the tumour particularly in the right ovary. In this site there are areas of extensive hemosiderin deposition which is consistent with the effects of hemorrhage related to tissue necrosis.

Clinical History as Provided by Submitting Physician:

Now taken for debulking and incisional hernia repair

A. (L) ovary and tube

B. Right ovary and fallopian tube

Specimens Received:

A: left ovary and tube

B: right ovary and fallopian tube

Gross Description:

Specimen is received in two containers both labelled with the patient's name.

Container "A" is labelled "left ovary plus tube" and consists of the same. The left fallopian tube measures 4.5 cm in length, 0.3 cm in diameter. The left ovary measures 4.5 x 2.7 x 2 cm. The serosa overlying adnexa is roughened with coarse adhesions. Cross section of the ovary shows tan-white nodule measuring 1.9 cm in greatest dimension with central cyst filled with mucinous content. The nodule is abutting the inked surface.

Representative sections are submitted as follows:

"A1"- "A3"-ovary

"A4" -fallopian tube

Container "B" is labelled "right ovary plus tube" and consists of the same. The fallopian tube is submitted separately from the ovary and measures 4.5 cm and 1.7 cm in diameter. The external surface of the fallopian tube is covered with coarse adhesions. The ovary measures 7 cm x 4.5 x 3 cm and consists of a previously opened unilocular cyst measuring 6.5 x 3.5 x 3.5 cm. The external surface of the cyst is smooth, roughened with a few adhesions and it is focally inked black. The inner lining of the cyst shows papillary growth measuring 5.4 x 2.5 cm that on cross section shows tan-white structure with cystic areas alternated by tan-white fibrose with thickness of 3.3 cm. The tumor is grossly abutting the ink margin.

Representative sections are submitted as follows:

[page 2 of 2]
"B1"- "B3" -ovary
"B4" -fallopian tube

Copies to:

Source: NCI Genomic Data Commons file 56cdf2ed-21e8-46b4-a33b-9aaa9371c67e (TCGA-36-1576.2EB0B46A-ECD3-43B4-BFC2-E1C5E6101D1F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).